Somatic mutation profile of tumor specimen TARGET-30-PAMDAL-01A (aliquot TARGET-30-PAMDAL-01A-01W) from TARGET case TARGET-30-PAMDAL, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.3 years (1,222 days).
Specimen TARGET-30-PAMDAL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0122238b-5bab-4e39-a119-b7adcb1d77ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMDAL-10A (Blood Derived Normal), aliquot TARGET-30-PAMDAL-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc2bd786-f870-4e65-b207-f86e6deab813

The open-access MAF lists 23 somatic variants for this specimen: 22 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 21, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF21A | c.1168C>T p.R390* (on ENST00000418153 / NM_001101802.3; = p.R391* on NM_016621.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 33/230 reads (14%) | catalogued as rs1554988946, COSV57648732; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFP | c.770A>G p.K257R | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV56923806; called by muse, mutect2, varscan2
- CACNB3 | c.824A>T p.N275I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56397019; called by muse, mutect2, varscan2
- CBL | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs587778162, COSV50629765; ClinVar: not provided; called by muse, mutect2, varscan2
- CCNB3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.429); catalogued as COSV52069687; called by muse, mutect2, varscan2
- DCDC1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as rs931421406, COSV60833505; called by muse, mutect2, varscan2
- DNTT | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.618); catalogued as COSV64522593; called by muse, mutect2, varscan2
- FBLN2 | c.2803G>A p.A935T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55480585; called by muse, mutect2, varscan2
- GRM5 | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.982); catalogued as COSV59589246; called by muse, mutect2, varscan2
- NLRC4 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 100/408 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs1354596095, COSV61591239; called by muse, mutect2, varscan2
- OR2T1 | c.355T>A p.Y119N | Missense Mutation (SNP) | VAF 48/462 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63541120; called by muse, mutect2, varscan2
- PAPLN | c.1997G>T p.C666F (on ENST00000554301; = p.C639F on NM_173462.4) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53712774; called by muse, mutect2, varscan2
- RP1 | c.4539T>A p.N1513K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV55109559; called by muse, mutect2, varscan2
- SH3TC1 | c.2590G>A p.V864M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs368042560; called by muse, mutect2, varscan2
- TAF1 | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.085); catalogued as COSV52106907; called by muse, mutect2, varscan2
- TANC2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755972267; called by muse, mutect2
- TBC1D8B | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 66/407 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV52175426; called by muse, mutect2, varscan2
- TSPYL5 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1172836039, COSV59070908, COSV59071533; called by muse, mutect2, varscan2
- UTRN | c.8576G>A p.R2859H | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147541840; called by muse, mutect2
- ZNF221 | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs754711744, COSV52107892; called by muse, mutect2, varscan2
- VN1R2 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by mutect2, varscan2
- ZNF587 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 26/365 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- BCLAF1 | c.681T>C p.H227= | Silent (SNP) | VAF 36/284 reads (13%) | catalogued as COSV62140257; called by muse, mutect2
